Somatic mutation profile of tumor specimen ALCH-B1UQ-TTP1-A (aliquot ALCH-B1UQ-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1UQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.6 years (22,868 days).
Specimen ALCH-B1UQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82d22b89-b7d1-4b2b-a533-c0ad2631adcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1UQ-NB1-A (Blood Derived Normal), aliquot ALCH-B1UQ-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/614e8617-4aee-4f3d-8902-0f09f8ab0a67

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 4, RNA 3, Intron 2, Frame Shift Del 2, 3'UTR 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.7976T>G p.F2659C | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs1288798561; called by muse, mutect2
- ADGRE1 | c.2106C>A p.Y702* | Nonsense Mutation (SNP) | VAF 14/466 reads (3%) | catalogued as COSV51681236; called by muse, mutect2
- BACH2 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 20/604 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1460936502, COSV57599410; called by muse, mutect2
- CFAP65 | c.1190C>A p.S397Y | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV55390919, COSV99838486; called by muse, mutect2
- GAPVD1 | c.2476G>T p.A826S (on ENST00000394104; = p.A853S on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV52919841; called by muse, mutect2
- IGLV3-9 | c.207T>G p.D69E | Missense Mutation (SNP) | VAF 111/883 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as rs769122017; called by muse, mutect2, varscan2
- SURF6 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs782688340, COSV100921124; called by muse, mutect2, varscan2
- TNF | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 50/294 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.762); catalogued as COSV69304669, COSV69305458; called by muse, mutect2, varscan2
- TUBG1 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 17/497 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99258496; called by muse, mutect2
- ADAMTS10 | c.1106T>C p.M369T | Missense Mutation (SNP) | VAF 85/279 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ANKRD35 | c.1302G>C p.E434D | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.169); called by muse, mutect2
- C2CD5 | c.433A>C p.K145Q | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPHA3 | c.86A>G p.E29G | Missense Mutation (SNP) | VAF 69/292 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- FCGR2B | c.258C>A p.H86Q | Missense Mutation (SNP) | VAF 60/764 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- FRG2C | c.146C>G p.S49C | Missense Mutation (SNP) | VAF 74/1054 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- GRIN3B | c.798del p.K267Rfs*90 | Frame Shift Del (DEL) | VAF 61/258 reads (24%) | called by mutect2, pindel, varscan2
- LRP2 | c.4046A>G p.N1349S | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- PFKFB3 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 14/226 reads (6%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- PLS3 | c.1228C>G p.L410V | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2
- RESF1 | c.716A>G p.H239R | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNPO | c.93G>C p.R31S | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.33); called by muse, mutect2
- TTBK2 | c.3619G>A p.E1207K | Missense Mutation (SNP) | VAF 101/562 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ZNF706 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ZNF750 | c.1660_1661del p.S554Gfs*6 | Frame Shift Del (DEL) | VAF 52/230 reads (23%) | called by pindel, varscan2
- GAPVD1 | c.2475G>C p.L825= (on ENST00000394104; = p.L852= on NM_015635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/317 reads (11%) | called by muse, mutect2, varscan2
- MEGF8 | c.8445G>T p.G2815= (on ENST00000251268 / NM_001271938.2; = p.G2748= on NM_001410.3) | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- NID2 | c.2652C>T p.A884= | Silent (SNP) | VAF 20/185 reads (11%) | catalogued as rs746918916, COSV53494382; called by muse, mutect2, varscan2
- OR1M1 | c.420C>T p.L140= | Silent (SNP) | VAF 7/157 reads (4%) | called by muse, mutect2
- CDH15 | c.*31C>T | 3'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as rs370773912; called by mutect2, varscan2
- DPP9 | c.1944+291G>T | Intron (SNP) | VAF 28/107 reads (26%) | called by muse, mutect2, varscan2
- GSDME | c.990+760G>A | Intron (SNP) | VAF 40/1498 reads (3%) | called by muse, mutect2
- HAND2-AS1 | n.452_454del | RNA (DEL) | VAF 20/143 reads (14%) | called by mutect2, pindel, varscan2
- HNRNPA3P1 | n.663C>T | RNA (SNP) | VAF 58/343 reads (17%) | catalogued as rs1468037298; called by muse, mutect2, varscan2
- HSD17B7P2 | n.471C>T | RNA (SNP) | VAF 21/173 reads (12%) | called by muse, mutect2, varscan2
- ZNF606 | c.-256G>A | 5'UTR (SNP) | VAF 46/174 reads (26%) | catalogued as COSV58350730; called by muse, mutect2, varscan2
